Somatic mutation profile of tumor specimen TARGET-20-PASANW-09A (aliquot TARGET-20-PASANW-09A-01D) from TARGET case TARGET-20-PASANW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.7 years (4,986 days).
Specimen TARGET-20-PASANW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f2532a2-ad83-44ad-8e53-2d862300ee3c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASANW-14A (Bone Marrow Normal), aliquot TARGET-20-PASANW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20e96a9f-e6a0-40e1-8954-e84876ed89e0

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GATA2 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs765555593; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC3 | c.1464_1466del p.E488del | In Frame Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs863223279; called by pindel, varscan2
- CCDC8 | c.*430A>T | 3'UTR (SNP) | VAF 46/107 reads (43%) | called by muse, mutect2, varscan2
